Somatic mutation profile of tumor specimen C3N-03226-02 (aliquot CPT0194420009) from CPTAC case C3N-03226, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 54.6 years (19,938 days).
Specimen C3N-03226-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e195a675-02aa-4615-89e6-600650b8b50c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03226-71 (Blood Derived Normal), aliquot CPT0194530002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92d9c2a4-ef4c-44ab-be7b-3e8564c09474

The open-access MAF lists 56 somatic variants for this specimen: 32 protein-altering or splice-affecting, 13 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 13, Intron 6, Nonsense Mutation 3, 3'Flank 2, Frame Shift Del 1, 5'UTR 1, Frame Shift Ins 1, 5'Flank 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 172/916 reads (19%) | hotspot (GDC flag); catalogued as rs121913384, CM034218, CM095540, COSV58683071, COSV58683670; ClinVar: likely pathogenic; called by muse, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 30/157 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 48/341 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSL1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs762658676, COSV55663671; called by muse, mutect2
- AQR | c.3340A>G p.N1114D | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs763802425; called by muse, mutect2
- KIF24 | c.2089G>A p.G697S | Missense Mutation (SNP) | VAF 60/309 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs199521804; called by muse, mutect2, varscan2
- KNL1 | c.3775C>T p.L1259F (on ENST00000346991 / NM_170589.5; = p.L1233F on NM_144508.5) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs1484416003; called by muse, mutect2, varscan2
- LAMB2 | c.3469C>T p.R1157C | Missense Mutation (SNP) | VAF 56/386 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs747064604, COSV100026320; called by muse, mutect2, varscan2
- MAP3K1 | c.971C>A p.P324H | Missense Mutation (SNP) | VAF 66/432 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68123876; called by muse, mutect2, varscan2
- MTSS2 | c.1891G>A p.A631T | Missense Mutation (SNP) | VAF 48/421 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.069); catalogued as rs760190663; called by muse, mutect2, varscan2
- MYO18B | c.3803G>A p.R1268H | Missense Mutation (SNP) | VAF 35/350 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1456129894; called by muse, mutect2, varscan2
- PDE1C | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 36/292 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58504841; called by muse, mutect2, varscan2
- PPM1L | c.114C>G p.Y38* | Nonsense Mutation (SNP) | VAF 22/266 reads (8%) | catalogued as COSV101534476; called by muse, mutect2
- PRKCZ | c.1003G>A p.G335S | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1439516416; called by muse, mutect2
- SIGLEC12 | c.908C>T p.T303M (on ENST00000291707 / NM_053003.4; = p.T185M on NM_033329.2) | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.955); catalogued as rs778436707, COSV52464527; called by muse, mutect2
- USH2A | c.366C>A p.S122R | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs749609528; called by muse, mutect2
- ADGRE2 | c.1590+1G>A p.X530_splice | Splice Site (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- CLN6 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 16/117 reads (14%) | called by muse, mutect2, varscan2
- EHBP1 | c.981A>T p.E327D | Missense Mutation (SNP) | VAF 32/342 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.022); called by muse, varscan2
- KIAA1614 | c.1773G>A p.M591I | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- LRFN4 | c.727C>A p.L243M | Missense Mutation (SNP) | VAF 18/414 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.844); called by muse, mutect2
- LRP6 | c.3061A>G p.I1021V | Missense Mutation (SNP) | VAF 44/398 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- MCOLN1 | c.1510C>G p.L504V | Missense Mutation (SNP) | VAF 62/629 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2
- MIS18BP1 | c.1187A>G p.N396S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- MYH3 | c.4353C>G p.D1451E | Missense Mutation (SNP) | VAF 14/474 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2
- NLRP3 | c.1894_1934del p.L632Gfs*7 | Frame Shift Del (DEL) | VAF 41/383 reads (11%) | called by mutect2, pindel
- NOTCH1 | c.2414_2418dup p.I807Rfs*71 | Frame Shift Ins (INS) | VAF 76/523 reads (15%) | called by mutect2, pindel, varscan2
- RELN | c.5576C>T p.T1859I | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- RNGTT | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.792); called by muse, mutect2
- WNK1 | c.4337C>G p.A1446G (on ENST00000315939 / NM_018979.4; = p.A1199G on NM_014823.3) | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZBED4 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.657); called by muse, mutect2
- ZFYVE1 | c.584A>G p.H195R | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ACAP3 | c.2091G>A p.A697= | Silent (SNP) | VAF 72/594 reads (12%) | catalogued as rs1462681568; called by muse, mutect2, varscan2
- ANKS6 | c.51T>C p.C17= | Silent (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2
- COX7A1 | c.90G>A p.Q30= | Silent (SNP) | VAF 37/283 reads (13%) | called by muse, mutect2, varscan2
- FGF23 | c.477C>T p.S159= | Silent (SNP) | VAF 38/414 reads (9%) | catalogued as rs1390422854, COSV99426691; called by muse, mutect2
- GFPT2 | c.1323C>T p.G441= | Silent (SNP) | VAF 33/326 reads (10%) | catalogued as rs753867862; called by muse, mutect2
- LAMA5 | c.4188A>G p.K1396= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as rs773620331; called by muse, mutect2
- MAGEB10 | c.981C>A p.R327= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV63310399; called by muse, mutect2
- PCDHB2 | c.921G>A p.Q307= | Silent (SNP) | VAF 15/99 reads (15%) | called by muse, mutect2, varscan2
- PCDHGB3 | c.2112C>A p.L704= | Silent (SNP) | VAF 47/391 reads (12%) | catalogued as COSV53898919; called by muse, mutect2, varscan2
- PPP2R3B | c.1017G>C p.L339= | Silent (SNP) | VAF 29/740 reads (4%) | called by muse, mutect2
- RS1 | c.570G>T p.L190= | Silent (SNP) | VAF 36/167 reads (22%) | called by muse, mutect2, varscan2
- TJP3 | c.1302C>T p.F434= | Silent (SNP) | VAF 13/142 reads (9%) | catalogued as COSV53664043; called by muse, mutect2, varscan2
- TMEM39B | c.1041G>A p.L347= | Silent (SNP) | VAF 48/540 reads (9%) | called by muse, mutect2
- CLUAP1 | c.1092+328T>A | Intron (SNP) | VAF 21/174 reads (12%) | called by muse, mutect2, varscan2
- CWH43 | c.-13C>G | 5'UTR (SNP) | VAF 24/280 reads (9%) | catalogued as rs770684695; called by muse, mutect2
- GIP | c.*5G>T | 3'UTR (SNP) | VAF 8/236 reads (3%) | catalogued as rs959957964; called by muse, mutect2
- IL12A | c.462+14C>A | Intron (SNP) | VAF 55/294 reads (19%) | called by muse, mutect2, varscan2
- MFRP | chr11:119344877 G>A | 5'Flank (SNP) | VAF 60/602 reads (10%) | catalogued as rs771487710, COSV64127953, COSV64128712; called by muse, mutect2
- MIR6511A3 | chr16:16371483 G>A | 3'Flank (SNP) | VAF 82/1426 reads (6%) | catalogued as rs764207709; called by muse, mutect2
- RFX5 | c.354-32G>A | Intron (SNP) | VAF 21/192 reads (11%) | catalogued as rs377364866; called by muse, mutect2, varscan2
- RPL37AP1 | chr20:44465256 G>A | 3'Flank (SNP) | VAF 4/42 reads (10%) | catalogued as rs899569098; called by muse, mutect2
- SPATA18 | c.1479+32C>T | Intron (SNP) | VAF 30/334 reads (9%) | called by muse, mutect2
- SPG7 | c.2160+29C>T | Intron (SNP) | VAF 42/417 reads (10%) | catalogued as rs368495277; called by muse, mutect2, varscan2
- UBE2E3 | c.245+5852T>C | Intron (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
